Surgical pathology report (de-identified scan), TCGA case TCGA-55-6970, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6970-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected [REDACTED] Received: [REDACTED] Complete [REDACTED]

Pre-Op Diagnosis : Non Small Cell Cancer
Order Physician : [REDACTED]
Specimens : Lung Tissue, right
Lung, Right Upper Lobe
Lymph Node, St 8, Paraesophageal
Lymph Node, St 4, Lower Paratracheal

Frozen Diagnosis :

Report : GROSS EXAMINATION.

A. The specimen is received in a container labeled with the name of the patient and labeled as lung tissue, right. The specimen consists of a great tan rubbery irregular piece of tissue which measures 1.5 x 1.0 x 0.7 cm. The specimen is bisected and totally submitted.

B. The specimen is received in a container labeled with the name of the patient and labeled as lung, right upper lobe. The specimen consists of a lobe of lung which measures 14.5 x 11.5 x 3.5 cm. The bronchial margins are submitted in block one. Near the bronchial margins is an anthracotic lymph node which is submitted in block two. The serosal surface is pink tan with anthracotic stippling. Sectioning through the specimen reveals pink to red brown crepitant lung tissue. Located 1.5 cm from the bronchial margins is a gray tan nodular lesion which measures 3.5 x 3.0 x 2.0 cm. The tumor approaches to within 0.7 cm of the pleural surface. No other areas of lesion are grossly identified. Sections of tumor are submitted in block's three through six and a section of lung tissue distance from the area of lesion is submitted in block seven. A portion of this tumor is submitted for [REDACTED].

C. The specimen is received in a container labeled with the name of the patient and labeled as lymph node station eight, paraesophageal. The specimen consists of a gray tan to black anthracotic lymph node which measures 0.8 x 0.8 x 0.3 cm. The specimen is bisected in totally submitted.

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#: [REDACTED]
Path #: [REDACTED]
Visit #: [REDACTED]

Page 1 of 3

[page 2 of 3]
[REDACTED]

D. The specimen is received in a container labeled with the name of the patient and labeled as lymph node, station 4R, lower paratracheal. The specimen consists of two tan fragments of rubbery tissue measuring in aggregate 1.2 x 0.6 x 0.3 cm. The specimen is totally submitted. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

A. Right pulmonary lymph node (excisional biopsy):
Metastatic papillary adenocarcinoma.
[T-C4000 M-81406 196.9 P3-44050]

B. LUNG resection.
SPECIMEN TYPE: Lobectomy.
LATERALITY: Right.
TUMOR SITE: Upper lobe.
TUMOR SIZE: 3.5 x 3.0 x 2.0 cm
HISTOLOGIC TYPE: Adenocarcinoma, predominately papillary variant.
HISTOLOGIC GRADE: G2: Moderately differentiated.
PRIMARY TUMOR (PT): pT2: Tumor greater than 3 cm in greatest dimension.
REGIONAL LYMPH NODES (PN): pN2: Metastases in ipsilateral mediastinal and/or subcarinal lymph nodes.
Metastatic adenocarcinoma in one right pulmonary lymph node (specimen A, one peribronchial lymph node), and one of two lower paratracheal lymph nodes at station 8 (specimen D)/
DISTANT METASTASIS: pMX: Cannot be assessed.
MARGINS: Bronchial margin is involved by invasive carcinoma with papillary adenocarcinoma extensively involving lymphatics of submucosa and bronchial wall.
DIRECT EXTENSION OF TUMOR: None identified.
VENOUS (LARGE VESSEL) INVASION (V): Absent.
ARTERIAL (LARGE VESSEL) INVASION: Absent.
LYMPHATIC (SMALL VESSEL) INVASION (L): Present and extensive.

ADDITIONAL PATHOLOGIC FINDINGS: None.
[T-28000 M-81403 162.9 P3-44090]

C. Paraesophageal lymph node at station 8 (excisional biopsy): One lymph node negative for tumor.
[T-C4000 M-09470 V71.1 P3-44050]

D. Right lower paratracheal lymph node at station 8 (excision): Metastatic papillary adenocarcinoma in one of two lymph nodes.
[T-C4000 M-80006 196.9 P3-44070]

Intradepartmental consultation was obtained.

Pathologic stage: pT2N2MXG2.

[REDACTED] Pathologist
[REDACTED]

Electronically Signed by:

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#: [REDACTED]

Path #: [REDACTED]
Visit #: [REDACTED]

Page 2 of 3

[page 3 of 3]
THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#: [REDACTED]

Path #: [REDACTED]
Visit #: [REDACTED]

Page 3 of 3

Source: NCI Genomic Data Commons file afe4fc12-24d3-4d2a-8eb8-674e58c385f1 (TCGA-55-6970.1662FE4B-DA42-444A-B7FA-4990D9E8AA9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).